Somatic mutation profile of tumor specimen TCGA-DK-AA6P-01A (aliquot TCGA-DK-AA6P-01A-11D-A391-08) from TCGA case TCGA-DK-AA6P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 72.7 years (26,560 days).
Specimen TCGA-DK-AA6P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7cea465-39be-49a6-b448-91e9545969fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6P-10A (Blood Derived Normal), aliquot TCGA-DK-AA6P-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e43cb35d-d4e4-4a1e-83d7-d701b8b7ed15

The open-access MAF lists 178 somatic variants for this specimen: 135 protein-altering or splice-affecting, 35 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 35, Nonsense Mutation 15, Intron 5, Frame Shift Del 3, Splice Site 2, 5'Flank 1, 3'UTR 1, Splice Region 1, 5'UTR 1, Translation Start Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*164G>T | 3'UTR (SNP) | VAF 80/138 reads (58%) | catalogued as rs121913479, CM960656, COSV53390089, COSV99600444; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13718C>A p.S4573* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as COSV101291392, COSV68945754; called by muse, mutect2
- ACTL9 | c.629A>G p.Q210R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61007264; called by muse, mutect2, varscan2
- AHNAK2 | c.8164C>T p.P2722S | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV60931327; called by muse, mutect2
- ALG10 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56791937; called by muse, mutect2, varscan2
- AMBRA1 | c.2053G>C p.E685Q (on ENST00000458649 / NM_001367468.1; = p.E595Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV54062824; called by muse, mutect2, varscan2
- APOE | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV52986586; called by muse, mutect2, varscan2
- APOLD1 | c.633C>G p.I211M (on ENST00000326765 / NM_001130415.2; = p.I180M on NM_030817.3) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV58734356; called by muse, mutect2
- ARHGAP25 | c.1213G>C p.D405H (on ENST00000409202 / NM_001007231.3; = p.D397H on NM_014882.3) | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as rs1216948875, COSV54909310; called by muse, mutect2, varscan2
- ARID1A | c.4799C>T p.S1600F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61389307; called by muse, mutect2, varscan2
- ASH1L | c.6208G>A p.D2070N (on ENST00000368346 / NM_001366177.2; = p.D2065N on NM_018489.3) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV64213970; called by muse, mutect2, varscan2
- AZI2 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.41); catalogued as rs1445258343, COSV55423799, COSV55424513; called by muse, mutect2, varscan2
- BFSP2 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs967639640, COSV56592135; called by muse, mutect2, varscan2
- BPIFC | c.1280T>G p.I427S | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV53280605; called by muse, mutect2
- C1orf198 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV64176684; called by muse, mutect2, varscan2
- C2orf80 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58019280; called by muse, mutect2, varscan2
- CCRL2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV62193705; called by muse, mutect2
- CD14 | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 38/46 reads (83%) | catalogued as COSV100117594, COSV57370764; called by muse, mutect2, varscan2
- CD1E | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100937036, COSV63771684; called by muse, mutect2
- CD86 | c.335T>C p.I112T (on ENST00000330540 / NM_175862.5; = p.I106T on NM_006889.4) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52610432; called by muse, mutect2, varscan2
- CEP192 | c.2330A>G p.N777S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs545371450, COSV58070786; called by muse, mutect2, varscan2
- CHEK2 | c.128_129del p.T43Kfs*33 | Frame Shift Del (DEL) | VAF 115/172 reads (67%) | catalogued as COSV60426522; called by mutect2, pindel, varscan2
- CNNM4 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100998766; called by muse, mutect2
- COL4A4 | c.3698G>A p.G1233E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636762; called by muse, mutect2, varscan2
- DDX52 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs139568647; called by muse, mutect2, varscan2
- DIP2B | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 124/193 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV56592303; called by muse, mutect2, varscan2
- DLG5 | c.1440C>T p.I480= | Splice Region (SNP) | VAF 5/61 reads (8%) | catalogued as COSV64950036; called by muse, mutect2
- DSCAM | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs764389856, COSV68036492; called by muse, mutect2, varscan2
- DUT | c.712G>A p.D238N (on ENST00000331200 / NM_001025248.2; = p.D150N on NM_001948.4) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV58664724; called by muse, mutect2
- EHHADH | c.1811G>C p.R604T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51633609; called by muse, mutect2, varscan2
- EIF4G3 | c.4090T>C p.C1364R | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51694459; called by muse, mutect2, varscan2
- EIF5B | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV56816798; called by muse, mutect2
- EML1 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51753021, COSV99215097; called by muse, mutect2, varscan2
- ENKD1 | c.879G>C p.Q293H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV54669965; called by muse, mutect2, varscan2
- ERBB3 | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 212/270 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV57253171, COSV57263580; called by muse, mutect2, varscan2
- FCMR | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV65569591; called by muse, mutect2, varscan2
- FO393400.1 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV54069718, COSV54070793, COSV54071075; called by muse, mutect2
- FZD2 | c.361T>G p.C121G | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59530290; called by muse, mutect2, varscan2
- GABRA4 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51935376; called by muse, mutect2, varscan2
- GRIK3 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV66147135; called by muse, mutect2
- GRIK5 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV53486116; called by muse, mutect2, varscan2
- GRM7 | c.1142C>G p.S381* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100737613; called by muse, mutect2
- HERC6 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV52028637, COSV52034870; called by muse, mutect2, varscan2
- HMCN1 | c.15199G>A p.D5067N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as COSV99632919; called by muse, mutect2
- HOXB1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53317037; called by muse, mutect2
- IGSF9B | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs886617015, COSV58072928; called by muse, mutect2, varscan2
- IL6ST | c.1517G>A p.S506N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV61142998; called by muse, mutect2
- IRF2 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66929934, COSV66930646; called by muse, mutect2, varscan2
- ITGA2 | c.1786A>G p.I596V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV56866639; called by muse, mutect2, varscan2
- KANSL1 | c.2664-1G>T p.X888_splice (on ENST00000574590 / NM_001193465.2; = p.X889_splice on NM_015443.4) | Splice Site (SNP) | VAF 41/80 reads (51%) | catalogued as COSV52274205, COSV99294568; called by muse, mutect2, varscan2
- KDM6A | c.409G>C p.G137R | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65046121; called by muse, mutect2, varscan2
- KIT | c.1320G>A p.W440* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99854905; called by muse, mutect2
- KRT15 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1445365258, COSV54178622; called by muse, mutect2, varscan2
- L3MBTL4 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53141013; called by muse, mutect2, varscan2
- LMO7 | c.615C>A p.D205E (on ENST00000357063; = p.D220E on NM_005358.5) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV58549369; called by muse, mutect2
- LRP6 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 67/85 reads (79%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV53794829; called by muse, mutect2, varscan2
- LRRC37A3 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 114/240 reads (48%) | catalogued as rs1224513104, COSV100141310; called by muse, mutect2, varscan2
- LSM10 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV59872683; called by muse, mutect2, varscan2
- LYST | c.5330C>G p.S1777* | Nonsense Mutation (SNP) | VAF 5/125 reads (4%) | catalogued as COSV67703588; called by muse, mutect2
- MCM7 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV57999053; called by muse, mutect2, varscan2
- MVD | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99880098; called by muse, mutect2, varscan2
- MYO3A | c.4179G>T p.L1393F | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV56349985; called by muse, mutect2, varscan2
- MYOC | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV50679209, COSV99231790; called by muse, mutect2, varscan2
- NAV3 | c.1595C>A p.S532Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV57112923; called by muse, mutect2, varscan2
- NCF4 | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.391); catalogued as COSV50627321, COSV50628331; called by muse, mutect2, varscan2
- NF1 | c.7501G>T p.E2501* (on ENST00000358273 / NM_001042492.3; = p.E2480* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as COSV62209962, COSV62214761; called by muse, mutect2, varscan2
- NOTCH3 | c.5249G>A p.W1750* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs1461629418, COSV99658182; called by muse, mutect2, varscan2
- NPAS4 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV60652864; called by muse, mutect2, varscan2
- NPHP3 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757710406, COSV58633649; called by muse, mutect2, varscan2
- OCIAD2 | c.248C>A p.S83* | Nonsense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV56717220, COSV99906648; called by muse, mutect2
- OIP5 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); catalogued as COSV52973366; called by muse, mutect2, varscan2
- OR4K13 | c.833del p.F278Sfs*5 | Frame Shift Del (DEL) | VAF 16/22 reads (73%) | catalogued as rs1441359997; called by mutect2, pindel, varscan2
- OR8B12 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV60912901; called by muse, mutect2, varscan2
- OR8I2 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as COSV56170561; called by muse, mutect2
- OTOF | c.5415G>C p.K1805N (on ENST00000272371 / NM_194248.3; = p.K1038N on NM_004802.4) | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV55520352; called by muse, mutect2, varscan2
- PAQR3 | c.159C>A p.Y53* | Nonsense Mutation (SNP) | VAF 6/75 reads (8%) | catalogued as COSV99785313; called by muse, mutect2
- PCDHA9 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65323065, COSV65333024; called by muse, mutect2, varscan2
- PEG3 | c.2729G>A p.G910E | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.436); catalogued as COSV55648142; called by muse, mutect2
- PEX3 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 11/166 reads (7%) | catalogued as COSV100852218; called by muse, mutect2
- PFAS | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV58983340; called by muse, mutect2, varscan2
- PHKB | c.514-2A>T p.X172_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100068048; called by muse, mutect2
- PLA2R1 | c.3757C>A p.P1253T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51786927; called by muse, mutect2
- PLAGL2 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs769649938, COSV55789858; called by muse, mutect2, varscan2
- POSTN | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427585418, COSV65713165, COSV65714723; called by muse, mutect2
- PPP4R1 | c.119C>G p.S40* (on ENST00000400556 / NM_001042388.3; = p.S23* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53283110, COSV53284359, COSV99553801; called by muse, mutect2, varscan2
- PRKCE | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs1217458277, COSV60316951, COSV60330112; called by muse, mutect2, varscan2
- PSMB7 | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52332921; called by muse, mutect2
- PTPRO | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV55523259; called by muse, mutect2, varscan2
- RELN | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV59034165; called by muse, mutect2
- RGS14 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs1427998617, COSV68772028; called by muse, mutect2, varscan2
- RICTOR | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV57121325; called by muse, mutect2
- RNF128 | c.1060G>A p.E354K (on ENST00000255499 / NM_194463.2; = p.E328K on NM_024539.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV55254686; called by muse, mutect2
- RPL41 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 222/378 reads (59%) | catalogued as COSV57570577, COSV57570754, COSV99230638; called by muse, varscan2
- RPS6KA5 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56225840; called by muse, mutect2, varscan2
- SESN3 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV53585875, COSV99565902; called by muse, mutect2, varscan2
- SF3B1 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170618980, COSV59227954; called by muse, mutect2
- SH3D19 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs772895672, COSV58789967; called by muse, mutect2, varscan2
- SLC38A2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99874029; called by muse, mutect2, varscan2
- SLC9C2 | c.1647C>G p.I549M | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV62949612; called by muse, mutect2, varscan2
- SPACA9 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.189); catalogued as COSV62521389, COSV62522049; called by muse, mutect2
- SPEF2 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV56800549; called by muse, mutect2, varscan2
- SRCAP | c.8825C>T p.P2942L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV52681342; called by muse, mutect2, varscan2
- SREBF2 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV63332777; called by muse, mutect2, varscan2
- SRP68 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV57164759; called by muse, mutect2, varscan2
- STAG1 | c.3303G>C p.R1101S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV52624243; called by muse, mutect2, varscan2
- STK36 | c.2434C>G p.Q812E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV55330966; called by muse, mutect2, varscan2
- STON1 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV59131534; called by muse, mutect2
- TEK | c.1333C>A p.P445T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV66234800; called by muse, mutect2, varscan2
- TEP1 | c.7565C>G p.S2522C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV53000440; called by muse, mutect2, varscan2
- TINAGL1 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54700050; called by muse, mutect2, varscan2
- TSSK3 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV61983470; called by muse, mutect2, varscan2
- TULP3 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV68118773; called by muse, mutect2, varscan2
- UBE2D4 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV55974315; called by muse, mutect2, varscan2
- UROD | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55802029; called by muse, mutect2, varscan2
- USP34 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.102); catalogued as COSV68406771; called by muse, mutect2, varscan2
- UTRN | c.4384G>C p.D1462H | Missense Mutation (SNP) | VAF 149/152 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV62348327; called by muse, mutect2, varscan2
- WTAP | c.440T>G p.F147C | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61610380, COSV61610578; called by muse, mutect2, varscan2
- ZDHHC14 | c.1059G>C p.Q353H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58195403, COSV58196842; called by muse, mutect2, varscan2
- ZFP36L1 | c.519C>A p.C173* | Nonsense Mutation (SNP) | VAF 48/53 reads (91%) | catalogued as rs1488098280, COSV100322807; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV56274618; called by muse, mutect2, varscan2
- ZNF408 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV61239355; called by muse, mutect2, varscan2
- ZNF440 | c.1717G>C p.V573L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.114); catalogued as COSV58372588; called by muse, mutect2
- ZNF470 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV57970818; called by muse, mutect2
- ZNF492 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV71762393; called by muse, mutect2, varscan2
- ZNF492 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV101514033; called by mutect2, varscan2
- ZNF492 | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101514034; called by muse, mutect2
- ZNF568 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV61743098; called by muse, mutect2
- ZNF569 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 42/488 reads (9%) | catalogued as COSV100386564; called by muse, mutect2
- ZNF836 | c.1736A>G p.E579G | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59084471; called by muse, varscan2
- ACACA | c.4961C>G p.S1654C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); called by muse, mutect2
- IGHA1 | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- MGRN1 | c.621_626dup p.E207_G208dup | In Frame Ins (INS) | VAF 20/50 reads (40%) | called by mutect2, varscan2
- MUC16 | c.5579C>A p.A1860D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); called by muse, mutect2
- SUPT20HL1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- TM9SF4 | c.436_449del p.L146Rfs*4 | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | called by mutect2, pindel
- WASHC2C | c.3779C>G p.S1260C (on ENST00000336378; = p.S1239C on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ANAPC7 | c.1161C>T p.G387= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV71444067; called by muse, mutect2, varscan2
- AP2A2 | c.777C>T p.V259= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV59964050; called by muse, mutect2, varscan2
- APOH | c.30G>A p.S10= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1182597610, COSV52774556; called by muse, mutect2, varscan2
- ATXN10 | c.1017G>C p.V339= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV53300828; called by muse, mutect2, varscan2
- BRD1 | c.975G>A p.L325= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV53461735; called by muse, mutect2, varscan2
- CAPN7 | c.693G>A p.L231= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs1168083834, COSV53780866; called by muse, mutect2, varscan2
- CASP3 | c.783G>A p.Q261= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV57725902; called by muse, mutect2, varscan2
- CBFA2T2 | c.528A>G p.P176= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs1258214054, COSV60075966; called by muse, mutect2, varscan2
- CDH8 | c.963A>T p.T321= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100183325; called by muse, mutect2
- CUBN | c.3369C>T p.F1123= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as COSV64709039, COSV64727501; called by muse, mutect2, varscan2
- DCDC2B | c.303G>A p.K101= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs201678864, COSV52211321; called by muse, mutect2, varscan2
- DHX30 | c.1239C>A p.L413= (on ENST00000445061 / NM_138615.3; = p.L374= on NM_014966.3) | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV53142739; called by muse, mutect2, varscan2
- DUOX2 | c.4485C>T p.F1495= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs556008835, COSV66531861; called by mutect2, varscan2
- EPM2A | c.576C>T p.F192= | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as COSV62296712, COSV62297850; called by muse, mutect2
- FANCA | c.3417G>A p.L1139= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV59798653; called by muse, mutect2, varscan2
- GRIP1 | c.2316G>A p.L772= (on ENST00000359742 / NM_001379345.1; = p.L720= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 381/437 reads (87%) | catalogued as COSV54043535; called by muse, mutect2, varscan2
- GTPBP2 | c.1482G>A p.V494= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV61077408; called by muse, mutect2, varscan2
- HEATR1 | c.534G>A p.L178= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV63979575; called by muse, mutect2
- HEATR4 | c.1260C>G p.P420= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs779951152, COSV58572266, COSV58577541; called by mutect2, varscan2
- IL19 | c.390G>A p.R130= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV54284776; called by muse, mutect2, varscan2
- ITGA9 | c.853A>C p.R285= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV53253085; called by muse, mutect2, varscan2
- KLHL4 | c.459C>T p.T153= | Silent (SNP) | VAF 26/29 reads (90%) | catalogued as rs1388866332, COSV64148063; called by muse, mutect2, varscan2
- MGAT4B | c.192C>T p.L64= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV52979836; called by muse, mutect2, varscan2
- MRPS34 | c.657G>A p.*219= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs753331473, COSV99169406; called by muse, mutect2, varscan2
- MYADM | c.159G>A p.L53= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs777262125, COSV61241023; called by muse, mutect2, varscan2
- N4BP1 | c.528G>A p.L176= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52213397; called by muse, mutect2, varscan2
- NBAS | c.7050G>A p.V2350= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV55725351; called by muse, mutect2, varscan2
- NOTCH2 | c.2103G>A p.V701= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs587752252, COSV56706481; called by muse, mutect2, varscan2
- POLR2A | c.2550G>T p.T850= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- RAB27B | c.543C>T p.I181= | Silent (SNP) | VAF 28/33 reads (85%) | catalogued as rs1568118396, COSV50494632, COSV50494876; called by muse, mutect2, varscan2
- SPIN4 | c.603G>T p.V201= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV58738653; called by muse, mutect2, varscan2
- TP53I3 | c.378C>T p.L126= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs776891935, COSV99475480; called by muse, varscan2
- ZC3H8 | c.45C>G p.L15= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55620882; called by muse, mutect2, varscan2
- ZNF14 | c.1269A>G p.Q423= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as rs369555926; called by muse, mutect2, varscan2
- ZNF512B | c.444A>G p.A148= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV53878836; called by muse, mutect2, varscan2
- MAD1L1 | c.472-1472G>T | Intron (SNP) | VAF 10/23 reads (43%) | catalogued as rs1195562764, COSV99767067; called by muse, mutect2
- NACA | c.71-2330C>G | Intron (SNP) | VAF 7/60 reads (12%) | catalogued as COSV63273010; called by muse, mutect2, varscan2
- PNO1 | chr2:68157584 A>G | 5'Flank (SNP) | VAF 7/49 reads (14%) | called by mutect2, varscan2
- SPTBN4 | c.5915+70G>A | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as rs374217622; called by muse, mutect2, varscan2
- SRSF3 | c.341+844del | Intron (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- SYTL2 | c.1459+3252C>G | Intron (SNP) | VAF 14/52 reads (27%) | catalogued as COSV60363920; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 19/22 reads (86%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
